TCGA case TCGA-HU-A4GT — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: National Cancer Center Korea. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7997f3d8-bff6-4808-8df0-d88d344d7c9e

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: South Korea; Age at index: 71 years; Vital status: Alive.

Diagnoses (1)
1. Tubular adenocarcinoma: ICD-O-3 morphology code: 8211/3; ICD-10 code: C16.3; Tissue or organ of origin: Gastric antrum; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 71.8 years (26,231 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 198 days.
   Pathology details: Consistent pathology review: No; Lymph nodes positive: 0; Lymph nodes tested: 81.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Polysaccharide-K; Days to treatment start: 43 days; Days to treatment end: 100 days; Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Didox; Days to treatment start: 43 days; Days to treatment end: 279 days; Treatment outcome: Stable Disease.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 198 days; Disease response: Tumor Free.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-HU-A4GT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 140 mg.
  Slide TCGA-HU-A4GT-01A-02-TS2: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 20; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-HU-A4GT-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-HU-A4GT-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Intestinal Adenocarcinoma, Tubular Type; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Anatomic organ subdivision: Antrum/Distal; Lymph nodes examined: Yes; Cancer procurement city: Daegu; History barretts esophageal indicator: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Drug treatment 1: Pharmaceutical therapy drug name: Copolang.
- Drug treatment 2: Pharmaceutical therapy drug name: Didox.
- Follow-up form: Lost to follow-up: Yes; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 198 days; disease-specific survival: no event (censored), 198 days; disease-free interval: no event (censored), 198 days; progression-free interval: no event (censored), 198 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-HU-A4GT-01A-21D-A253-01): tumor purity 0.78, ploidy 2.22, whole-genome doublings 0.
